Somatic mutation profile of tumor specimen 0DG5AN from CCDI case PBBSZR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 13.5 years (4,927 days).
Specimen 0DG5AN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bce6d28-ec1d-4ed6-b341-a124f7d0df81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG5AD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aaa22fe7-009a-463f-a28f-73044b4eef6c

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SOX6 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 18/586 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV57038619; called by muse, mutect2
- SEMA6D | c.1146dup p.I383Hfs*6 | Frame Shift Ins (INS) | VAF 126/442 reads (29%) | called by mutect2, varscan2
- HMSD | c.366C>T p.F122= | Silent (SNP) | VAF 84/274 reads (31%) | catalogued as rs772541743, COSV68816777; called by muse, mutect2, varscan2
- PAPPA | c.*33C>T | 3'UTR (SNP) | VAF 67/227 reads (30%) | catalogued as rs202071577; called by muse, mutect2, varscan2
